Somatic mutation profile of tumor specimen TCGA-ZG-A9LZ-01A (aliquot TCGA-ZG-A9LZ-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LZ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.1 years (24,132 days).
Specimen TCGA-ZG-A9LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1edaf92-c5cc-4d21-8850-778f76e5aa89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LZ-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LZ-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c8bdae0-30f9-4c28-9a3d-5d3b4ffaa80e

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8812G>A p.V2938I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1334409232, COSV71286457; called by muse, mutect2
- AKAP1 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV100028186; called by muse, mutect2, varscan2
- AKAP4 | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278917707, COSV100654329; called by muse, mutect2, varscan2
- ATIC | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV99378067; called by muse, mutect2, varscan2
- C15orf40 | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100417416; called by muse, mutect2, varscan2
- CACNA1E | c.3055G>A p.V1019M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs547399351, COSV62386021; called by muse, mutect2, varscan2
- CLCA2 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100991654; called by muse, mutect2
- CSMD1 | c.3418G>A p.G1140S (on ENST00000520002; = p.G1139S on NM_033225.6) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372041329; called by muse, varscan2
- CXCL8 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56641434; called by muse, mutect2
- DHCR24 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs764133417, COSV100987838; called by muse, mutect2, varscan2
- DLG4 | c.1849C>T p.R617* (on ENST00000399506 / NM_001321075.3; = p.R660* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as rs767384318, COSV100263901; called by muse, mutect2, varscan2
- EBF1 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755362001, COSV58177645; called by muse, mutect2, varscan2
- FHL5 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459650, COSV58739537; called by muse, mutect2, varscan2
- FREM1 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as rs371449178; called by muse, mutect2, varscan2
- HOXD9 | c.60C>A p.Y20* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs745670260, COSV99982226; called by muse, mutect2, varscan2
- LTBP4 | c.4738G>T p.E1580* (on ENST00000308370 / NM_001042544.1; = p.E1543* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV52585635, COSV99199085; called by muse, mutect2, varscan2
- MBD5 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101290216; called by muse, mutect2, varscan2
- NRXN3 | c.3079C>T p.R1027C (on ENST00000335750 / NM_001330195.2; = p.R654C on NM_004796.6) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140301017; called by muse, mutect2, varscan2
- PPP2CB | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.545); catalogued as COSV99646724; called by muse, mutect2, varscan2
- PPP4R4 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs755834659, COSV58551388; called by muse, mutect2, varscan2
- SIGLEC1 | c.3613C>T p.L1205F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1189542754, COSV99170021; called by muse, mutect2, varscan2
- SPTA1 | c.4984G>T p.A1662S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs766252984, COSV63759600; called by muse, mutect2, varscan2
- TRPM1 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99856421; called by muse, mutect2
- ZNF574 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99726380; called by muse, mutect2, varscan2
- AC092143.1 | c.1314C>T p.I438= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV100206010; called by muse, mutect2, varscan2
- ARHGAP5 | c.261A>G p.E87= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100565617; called by muse, mutect2
- FNDC1 | c.1818G>A p.T606= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs769365417, COSV51938999; called by muse, mutect2, varscan2
- HEY2 | c.747C>T p.C249= | Silent (SNP) | VAF 41/209 reads (20%) | catalogued as rs995456849, COSV64240680; called by muse, mutect2, varscan2
- SYNE1 | c.13326C>T p.G4442= (on ENST00000367255 / NM_182961.4; = p.G4371= on NM_033071.3) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99574106; called by muse, mutect2, varscan2
